CCDI case PBBJZI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/32a9b87b-3325-43a5-ae25-fac528cb6904

Demographics
Sex at birth: female; Race: asian; Vital status: Alive.

Diagnoses (1)
1. Craniopharyngioma, adamantinomatous: ICD-O-3 morphology code: 9351/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.4 years (4,172 days).

Biospecimens (2 samples)
- Sample 0DAVIY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DAVLW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
